Somatic mutation profile of tumor specimen TCGA-ET-A3DW-01A (aliquot TCGA-ET-A3DW-01A-11D-A19J-08) from TCGA case TCGA-ET-A3DW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 64.6 years (23,603 days).
Specimen TCGA-ET-A3DW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 483da133-8a75-4a57-9aac-98437d11ba0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3DW-11A (Solid Tissue Normal), aliquot TCGA-ET-A3DW-11A-11D-A19J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cab6d16e-d7e2-4624-bb9d-3f17f5e5c3fa

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACVR2A | c.1373T>C p.I458T | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs1490498075, COSV54021809; called by muse, mutect2
- BMPER | c.308A>T p.E103V | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV51831442; called by muse, varscan2
- C10orf90 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV52956331, COSV52964050; called by muse, mutect2, varscan2
- KDSR | c.433A>T p.N145Y | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58508243; called by muse, mutect2, varscan2
- MYLPF | c.357C>T p.F119= | Splice Region (SNP) | VAF 3/10 reads (30%) | catalogued as COSV58443880; called by muse, mutect2
- NKX2-1 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61390270; called by muse, mutect2, varscan2
- PHF21A | c.1607T>C p.M536T (on ENST00000418153 / NM_001101802.3; = p.M490T on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV57659944; called by muse, mutect2, varscan2
- SEZ6L | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV50687319, COSV50693249; called by muse, mutect2, varscan2
- TSC22D2 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as COSV62623616; called by muse, mutect2, varscan2
- ZFP36 | c.449C>G p.T150R (on ENST00000594442; = p.T144R on NM_003407.5) | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50531426; called by muse, mutect2, varscan2
- ZNF101 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV58909968; called by muse, mutect2, varscan2
- ZNF644 | c.2092A>G p.M698V | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs529278742, COSV61350373; called by muse, mutect2, varscan2
- OR2J2 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2
- SLC34A2 | c.598dup p.A200Gfs*10 | Frame Shift Ins (INS) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- OR5F1 | c.498G>A p.L166= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV53548738; called by muse, mutect2, varscan2
- SLC26A9 | c.1608C>T p.S536= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as COSV61605454; called by muse, mutect2
- ZFHX3 | c.10947A>G p.S3649= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as COSV51735670; called by muse, mutect2, varscan2
